Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9HV, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9HV-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. UTERUS, BILATERAL TUBES AND OVARIES, SUPRACERVICAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY:
Uterine leiomyosarcoma, 14.9 cm, see comment.
Uterine leiomyomata, intramural and subserosal.
Tumor emboli present within vascular space of the right paratubal soft tissue.
Tumor present within the right parametrial tissue.
Bilateral ovaries with physiologic changes.
Left fallopian tube with xanthogranulomatous salpingitis.
Weakly proliferative endometrium.
Pathologic stage: T2 Nx Mx.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by _____

Comment

Sections show a hypercellular tumor with marked atypia, areas of necrosis and increased mitosis. The above findings are compatible with a diagnosis of leiomyosarcoma.

Specimen(s) Received

- A. UTERUS, TUMOR, BILATERAL TUBES AND OVARIES

Clinical History

-year-old white female.

Preoperative Diagnosis

Uterine leiomyosarcoma.

ICD O-3
Leiomyosarcoma NOS 8890/3
Site: Uterus NOS C55.9
JAO 4/22/14

Gross Description

- A. The specimen is received fresh labeled "uterus, bilateral tubes and ovaries" and consists of a 1319 gram, markedly distorted, 17.2 x 9.8 x 13.4 cm, supracervical uterus with attached adnexa. The serosa is focally shaggy and congested on the right lateral wall and fundus. On opening, there is a submucosal polyp distorting the endometrial cavity. Sectioning reveals a 14.9 x 9.8 cm, lobulated, focally congested, glistening, tan gray tumor with approximately 15% necrosis. The tumor extends up to the disrupted serosa at the right cornu. The endometrial surface is glistening, tan and 0.1 cm in thickness. The myometrium is dense, tan gray and 3.2 cm in thickness. It contains 3 intramural, bulging, whorled, dense, gray white nodules which measure up to 5.0 cm. The 6.5 cm right fallopian

[page 2 of 2]
tube is edematous, purple gray. Sectioning reveals a patent lumen. The 2.5 x 1.8 x 1.1 cm right ovary is smooth, lobulated, tan gray. Sectioning reveals a dense, tan, grey stroma. The previously-transected, 6.5 cm left fallopian tube is smooth to shaggy, purple gray. Sectioning reveals a dilated lumen filled with tan yellow material. The 2.7 x 2.5 x 1.6 cm left ovary is smooth to shaggy, purple gray. Sectioning reveals a 1.5 cm hemorrhagic subcortical cyst. The stroma is dense, purple gray. Representative sections are submitted as labeled:

- A1-A5: Full-thickness tumor to disrupted serosa
- A6-A7: Tumor to adjacent endometrium
- A8: Tumor to serosa at fundus
- A9: Tumor to adjacent myometrium
- A10: Largest myometrial nodule
- A11: Smaller myometrial nodules
- A12: Lower uterine segment
- A13: Right ovary and fallopian tube
- A14-A15: Left ovary and fallopian tube
- A16-A17: Right parametrium

Tissue is submitted to

Source: NCI Genomic Data Commons file 63cc3380-aba9-4562-a258-514c3ce8a3fc (TCGA-3B-A9HV.F6AB723C-DFF9-4E19-972A-38F1C890492E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).